Somatic mutation profile of tumor specimen TCGA-FD-A3SQ-01A (aliquot TCGA-FD-A3SQ-01A-21D-A22Z-08) from TCGA case TCGA-FD-A3SQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 62.1 years (22,687 days).
Specimen TCGA-FD-A3SQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aedb3d6b-638d-459a-8430-8075992315ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SQ-10A (Blood Derived Normal), aliquot TCGA-FD-A3SQ-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da41d755-ce98-4839-a992-2c0f6868e07e

The open-access MAF lists 83 somatic variants for this specimen: 60 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 22, Nonsense Mutation 8, Splice Site 3, Frame Shift Ins 2, In Frame Del 2, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.074); catalogued as rs572200577, COSV52461198; called by muse, mutect2, varscan2
- ANKS1B | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61379696; called by muse, mutect2, varscan2
- ARHGAP21 | c.5575C>T p.R1859C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs372867428; called by muse, mutect2, varscan2
- ARHGAP21 | c.5299G>C p.D1767H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57611850; called by muse, mutect2, varscan2
- ATP13A4 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV61328446; called by muse, mutect2, varscan2
- ATP1A3 | c.1158G>T p.Q386H (on ENST00000545399 / NM_001256214.2; = p.Q373H on NM_152296.5) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57491707; called by muse, mutect2
- ATP7A | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV58455324; called by muse, mutect2, varscan2
- BRSK1 | c.1890G>C p.S630= | Splice Region (SNP) | VAF 59/235 reads (25%) | catalogued as COSV58665656, COSV58670639; called by muse, mutect2, varscan2
- BTG2 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51858478; called by muse, mutect2
- CD6 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57836499; called by muse, mutect2, varscan2
- CHD9 | c.7472A>G p.N2491S (on ENST00000398510 / NM_001382353.1; = p.N2475S on NM_025134.7) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.614); catalogued as COSV54617395; called by muse, mutect2, varscan2
- CLSTN2 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs756270311, COSV71721294; called by muse, mutect2, varscan2
- CPXM2 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs373921701; called by muse, mutect2, varscan2
- CSMD1 | c.7966G>A p.V2656M (on ENST00000520002; = p.V2655M on NM_033225.6) | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV59393024; called by muse, mutect2, varscan2
- DDX60L | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs748422357, COSV52710829; called by muse, mutect2
- DNAJC11 | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50011941; called by muse, mutect2, varscan2
- EBF3 | c.1352C>T p.T451M (on ENST00000355311 / NM_001375392.1; = p.T442M on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs771970438, COSV62474563; called by muse, mutect2, varscan2
- ELF2 | c.1432C>G p.L478V (on ENST00000379550 / NM_001331036.2; = p.L418V on NM_006874.4) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.214); catalogued as COSV55496322; called by muse, mutect2, varscan2
- EMB | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.381); catalogued as COSV57484918, COSV57484979; called by muse, mutect2, varscan2
- ENPP1 | c.2308C>G p.Q770E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV62936256, COSV62936957; called by muse, varscan2
- FBN3 | c.2732-1G>C p.X911_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV54457572, COSV99561116; called by muse, mutect2
- FGF14 | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV65959754; called by muse, mutect2, varscan2
- GUCY2C | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV53787045; called by muse, mutect2
- IL31RA | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748001461, COSV61694232; called by muse, mutect2, varscan2
- IZUMO2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs1334566025, COSV53231558; called by muse, mutect2, varscan2
- LRP2 | c.12193C>T p.R4065* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as rs1228784624, COSV55545838; called by muse, mutect2, varscan2
- MAGEC3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71610266; called by muse, mutect2, varscan2
- MBIP | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.181); catalogued as COSV59255441; called by muse, mutect2, varscan2
- MYH7B | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.964); catalogued as COSV53423854, COSV53426261; called by muse, mutect2, varscan2
- NPPC | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54945730; called by muse, mutect2
- OMP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs782075647, COSV53685717, COSV99581949; called by muse, mutect2, varscan2
- OR2T1 | c.431T>A p.I144K | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV63543030; called by muse, mutect2
- OR6F1 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV57469683; called by muse, mutect2
- PCDHA13 | c.1508C>A p.A503E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV56551351; called by muse, varscan2
- PDCL | c.354+1G>T p.X118_splice | Splice Site (SNP) | VAF 45/108 reads (42%) | catalogued as COSV52343712; called by muse, mutect2, varscan2
- PGM1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1476203008, COSV64301694; called by mutect2, varscan2
- RGS7 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 145/251 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58563076; called by muse, mutect2, varscan2
- ROCK2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55085618; called by muse, mutect2, varscan2
- RTP3 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 40/131 reads (31%) | catalogued as COSV56123599; called by muse, mutect2, varscan2
- SLC6A17 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV58997311; called by muse, mutect2, varscan2
- TCTA | c.186_188del p.N62_T63delinsK | In Frame Del (DEL) | VAF 25/104 reads (24%) | catalogued as COSV55534530; called by mutect2, pindel, varscan2
- TSC1 | c.107-1G>T p.X36_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53774238; called by muse, mutect2, varscan2
- TTN | c.6179C>T p.T2060M (on ENST00000591111; = p.T2014M on NM_003319.4) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | PolyPhen probably damaging (0.963); catalogued as rs775339567, COSV60371209; called by muse, mutect2, varscan2
- VWC2 | c.911A>T p.Y304F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV61492274; called by muse, mutect2, varscan2
- WASF2 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as COSV71006838; called by muse, mutect2, varscan2
- XIRP2 | c.8853A>G p.I2951M (on ENST00000628543; = p.I3126M on NM_152381.6) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54738364, COSV54743693; called by muse, mutect2, varscan2
- ZCCHC8 | c.1824G>C p.Q608H | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV60320378; called by muse, mutect2, varscan2
- ZCWPW1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577472355, COSV61250747; called by muse, mutect2
- ZWILCH | c.954dup p.D319Rfs*3 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | catalogued as rs746390455; called by mutect2, varscan2
- CELSR1 | c.4167C>A p.C1389* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- CLSTN2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- DAAM1 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- DOCK3 | c.1765A>T p.K589* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- ELF3 | c.877dup p.M293Nfs*8 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- FAT4 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- PARP14 | c.2187C>G p.D729E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2
- RIF1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SPTAN1 | c.6278del p.F2093Sfs*2 | Frame Shift Del (DEL) | VAF 32/125 reads (26%) | called by mutect2, pindel, varscan2
- STAG2 | c.3558_3575del p.E1187_D1192del | In Frame Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- THBS4 | c.2625G>A p.W875* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- ABCC3 | c.3570C>T p.I1190= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as COSV53330437; called by muse, mutect2, varscan2
- ABCC3 | c.3624C>G p.L1208= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV53330455; called by muse, mutect2, varscan2
- ADAMTS2 | c.1593G>A p.G531= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV51071904, COSV51082417; called by muse, mutect2, varscan2
- BCL2L13 | c.1338C>T p.A446= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs1466209902, COSV58224929; called by muse, mutect2, varscan2
- CCKBR | c.183C>T p.Y61= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV58099318; called by muse, mutect2, varscan2
- CELSR1 | c.3906C>T p.F1302= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs756104205, COSV53101271; called by muse, mutect2, varscan2
- COL6A2 | c.189G>C p.T63= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV56017635; called by muse, mutect2, varscan2
- FAT4 | c.1885C>A p.R629= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV67901994; called by muse, mutect2, varscan2
- GBP6 | c.663G>A p.R221= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs1488237301, COSV65010776, COSV65012705; called by muse, mutect2
- GON4L | c.1470C>T p.L490= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV55205762; called by muse, mutect2, varscan2
- GPR4 | c.360C>T p.A120= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV59918655; called by muse, mutect2, varscan2
- HSD17B13 | c.822T>A p.P274= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV56347484; called by muse, mutect2, varscan2
- IL2RG | c.6G>A p.L2= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV52147362; called by muse, mutect2, varscan2
- INHBB | c.975C>T p.T325= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs368438939; called by muse, mutect2, varscan2
- INSR | c.4005T>C p.C1335= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV57174396; called by muse, mutect2, varscan2
- IQSEC3 | c.2328C>T p.P776= (on ENST00000538872 / NM_001170738.2; = p.P473= on NM_015232.1) | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as rs372227493; called by muse, mutect2
- MCM2 | c.975C>G p.V325= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV54037826; called by muse, mutect2, varscan2
- MYO18A | c.1608C>T p.Y536= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs772101766, COSV62874504; called by muse, mutect2, varscan2
- PHGDH | c.33C>T p.I11= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV65585019; called by muse, mutect2, varscan2
- UBA6 | c.1137C>T p.L379= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs768727125, COSV59181345; called by muse, mutect2, varscan2
- ZNF354B | c.882G>A p.V294= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV59367675; called by muse, mutect2, varscan2
- ZNF438 | c.1758G>A p.L586= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV100062582, COSV59201590; called by muse, mutect2, varscan2
- TTN | c.34264+2575C>T | Intron (SNP) | VAF 22/136 reads (16%) | catalogued as COSV100636616, COSV60388620; called by muse, mutect2
